Somatic mutation profile of tumor specimen BA2277D (aliquot aq-BA2277D) from BEATAML1.0 case 2044, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.6 years (26,519 days).
Specimen BA2277D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c98f27c8-1b41-47d0-92f2-a503d3c25c80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2892D (Solid Tissue Normal), aliquot aq-BA2892D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c3cfa03-c79d-4f0b-a0a2-11a3b8d871fa

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, 3'UTR 1, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 20/70 reads (29%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by pindel, varscan2
- COL4A2 | c.1778G>A p.G593D | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64627883; called by muse, mutect2, varscan2
- CYP2S1 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs768488156; called by muse, mutect2, varscan2
- HEG1 | c.3766G>A p.A1256T | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772002458, COSV60759766; called by muse, mutect2, varscan2
- LSS | c.1011G>T p.P337= | Splice Region (SNP) | VAF 5/111 reads (5%) | catalogued as rs759946114, COSV100711060, COSV100711091; called by muse, mutect2
- MYH14 | c.3613C>T p.R1205C | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1277975602; called by mutect2, varscan2
- CEBPA | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- KCNB1 | c.2465G>A p.G822E | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); called by mutect2, varscan2
- KIR3DL3 | c.973C>A p.L325M | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- RANBP17 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by mutect2, varscan2
- RTL1 | c.2623T>C p.F875L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SPTBN4 | c.2973C>A p.N991K | Missense Mutation (SNP) | VAF 3/57 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- TET2 | c.4653_4669delinsGAC p.H1551Qfs*22 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | called by pindel, varscan2*
- ACTL8 | c.957C>T p.H319= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs780320203; called by muse, mutect2
- SUGCT | c.27A>C p.A9= | Silent (SNP) | VAF 26/75 reads (35%) | called by muse, varscan2
- TIAL1 | c.93G>A p.Q31= | Silent (SNP) | VAF 35/94 reads (37%) | called by muse, mutect2, varscan2
- WBP2NL | c.507T>C p.P169= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- HDAC4 | c.*9C>T | 3'UTR (SNP) | VAF 66/154 reads (43%) | catalogued as rs765249256; called by muse, varscan2
